Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A177, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A177-01A (Primary Tumor).

[page 1 of 5]
100-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium 054.1

Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a mass (5.0 x 3.8 x 3.2 cm), located in the dome uterine wall. The tumor invades 1.3 cm into the myometrium (total wall thickness 1.4 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved.
- B. Lymph nodes, right pelvic, lymphadenectomy: Multiple (28) right pelvic lymph nodes are negative for tumor.
- C. Lymph nodes, left pelvic, lymphadenectomy: Multiple (17) left pelvic lymph nodes are negative for tumor.
- D. Lymph nodes, right peri-aortic below inferior mesenteric artery, lymphadenectomy: Multiple (7) right peri-aortic lymph nodes below inferior mesenteric artery are negative for tumor.
- E. Lymph nodes, right peri-aortic above inferior mesenteric artery, lymphadenectomy: Multiple (3) right peri-aortic lymph nodes above inferior mesenteric artery are negative for tumor.

[page 2 of 5]
F. Lymph nodes, left peri-aortic below inferior mesenteric artery,
lymphadenectomy: Multiple (3) right peri-aortic lymph nodes above inferior mesenteric artery are negative for tumor.

G. Lymph nodes, left peri-aortic above inferior mesenteric artery,
lymphadenectomy: Multiple (2) left peri-aortic lymph nodes above inferior mesenteric artery are negative for tumor.

With available surgical material [AJCC pT1bN0]

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ADDENDUM:

Source: Uterus, bilateral ovaries and fallopian tubes, block A2

Estrogen: Positive, 51-75% tumor nuclei staining.
Progesterone: Positive, 26-50% tumor nuclei staining.

Estrogen Receptor (ER) and Progesterone Receptor (PR) immunohistochemical (IHC) test results are only valid for non-decalcified paraffin embedded specimens fixed in formalin.

Testing is performed using monoclonal ER clone SP1 and PR clone PgR

636 and a polymer-based detection system. All controls show

[page 3 of 5]
appropriate reactivity. Reporting criteria for ER and PR IHC is based on 0% reactive cells is negative, 1-10% reactive cells is focal positive, and greater than 10% is positive.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, bilateral salpingo-oophorectomy" is a 99.8 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa smooth There is a 5.0 x 3.8 x 3.2 cm mass in the dome of the endometrial cavity which grossly appears to invade 1.4 cm into the 1.5 cm thick myometrium. There is a 1.6 x 0.8 x 0.7 cm right ovary with smooth outer surface and a solid cut surface with a 5.5 x 0.6 cm right fallopian tube. There is a 2.0 x 0.8 x 0.6 cm left ovary with a smooth outer surface and a solid cut surface with a 4.2 x 0.7 cm left fallopian tube. Representative sections are submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a 6.3 x 5.0 x 2.0 cm aggregate of adipose tissue and lymph nodes. All lymph nodes submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 6.0 x 6.0 x 2.3 cm aggregate of adipose tissue and lymph nodes. Lymph nodes submitted.

D. Received fresh labeled "right peri-aortic lymph nodes below IMA"

[page 4 of 5]
is a 4.5 x 2.5 x 1.0 cm aggregate of adipose tissue and lymph nodes.

Lymph nodes submitted.

E. Received fresh labeled "right peri-aortic lymph nodes above IMA"

is a 2.5 x 2.5 x 1.0 cm aggregate of adipose tissue and lymph nodes.

Lymph nodes submitted.

F. Received fresh labeled "left peri-aortic lymph nodes below IMA"

is a 3.0 x 3.0 x 1.0 cm aggregate of adipose tissue and lymph nodes.

Lymph nodes submitted.

G. Received fresh labeled "left peri-aortic lymph nodes above IMA"

is a 2.0 x 0.5 x 0.5 cm aggregate of adipose tissue and lymph nodes.

Lymph nodes submitted.

BLOCK SUMMARY:

Part A: Uterus, bilateral salpingo-oophorectomy

- 1 Cervix 6:00
- 2 Mass at deep
- 3 Mass 1
- 4 Mass 2
- 5 Right ovary & tube
- 6 Left ovary & tube

Part B: Right Pelvic Lymph Nodes

- 1 Right pelvic LN 4(B1)
- 2 Right pelvic LN 1(B2)
- 3 Right pelvic LN 2(B3)
- 4 Right pelvic LN 5(B4)
- 5 Right pelvic LN 2(B5)
- 6 Right pelvic LN 4(B6)
- 7 Rt pelvic ln 1(B7)
- 8 Rt pelvic ln 5 (B8)
- 9 Rt pelvic ln 3 (B9)
- 10 Rt pelvic ln 1 (B10)

Part C: Left Pelvic Lymph Nodes

- 1 Lt pelvic lns-5(C1)
- 2 Lt pelvic lns-1(C2)
- 3 Lt pelvic lns-1(C3)
- 4 Lt pelvic lns 1/2 (C4)

[page 5 of 5]
- 5 Lt pelvic lns 2/2 (C4)
- 6 Lt pelvic lns-2(C5)
- 7 Lt pelvic ln-3(C6)
- 8 Lt pelvic ln-1(C7)
- 9 Lt pelvic ln-1(C8)
- 10 Lt pelvic ln-4(C9)
- 11 Lt pelvic ln-1(C10)

Part D: Right below IMA Para-aortic Lymph Nodes

- 1 Rt paraaortic below IMA3(D1)
- 2 Rt paraaortic below IMA2(D2)
- 3 Rt paraaortic below IMA3(D3)

Part E: Right above IMA Para-aortic Lymph Nodes

- 1 Rt paraaortic above IMA3(E1)
- 2 Rt paraaortic above IMA2(E2)

Part F: Left below IMA Para-aortic Lymph Nodes

- 1 Lt paraaortic below IMA4(F1)
- 2 Lt paraaortic below IMA3(F2)

Part G: Left above IMA Para-aortic Lymph Nodes

- 1 Lt paraaortic above IMA2(G1)

Diagnostic Discrepancy		

Source: NCI Genomic Data Commons file 2a4fab27-7159-4490-9ada-71325eab0ecd (TCGA-D1-A177.28FF1BEE-6F93-4BCA-A6DC-56A1EA8EA337.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).